Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AATS, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AATS-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
Account #: [REDACTED] Date of Procedure: [REDACTED]
DOB: [REDACTED] (Age: [REDACTED]) Date of Receipt: [REDACTED]
Physician: [REDACTED] Date of Report: [REDACTED]
CC: [REDACTED]
Patient Address: [REDACTED]

....

Clinical Diagnosis & History:
Retroperitoneal mass.

Specimens Submitted:
1: SP: Radical resection of retroperitoneal mass, left iliac and distal
aorta left nephrectomy adrenal glands
2: SP: Aortic margin

DIAGNOSIS:

- 1) SOFT TISSUE, RETROPERITONEAL MASS, LEFT ILIAC ARTERY, LEFT
KIDNEY AND LEFT ADRENAL GLAND; EXCISION:
- HIGH GRADE SARCOMA WITH MYXOFIBROSARCOMA-LIKE FOCI AND OSSEOUS
DIFFERENTIATION (SEE COMMENT).
- TUMOR INVOLVES FIBROADIPOSE TISSUE, SKELETAL MUSCLE, ADVENTITIA OF SEGMENT
OF LARGE ARTERY, AND MUSCULARIS PROPRIA OF URETER.
- TUMOR MEASURES 12 CM GREATEST DIMENSION AND EXTENDS TO ANTERIOR,
POSTERIOR, SUPERIOR, AND INFERIOR MARGINS.
- TUMOR SHOWS 5% NECROSIS.
- LEFT KIDNEY SHOWS INTIMAL THICKENING OF INTERLOBULAR ARTERIES, MICROSCOPIC
CORTICAL ADENOMA, AND A SIMPLE CYST.
- ADRENAL GLAND SHOWING NO SIGNIFICANT HISTOPATHOLOGIC CHANGE.
- TWO BENIGN RENAL HILAR LYMPH NODES.

COMMENT: IMMUNOSTAINS ARE NEGATIVE FOR CDK4, MDM2, AE1/AE3, 34BE12, EMA, CAM
5.2, DESMIN, AND MYOGENIN. FINDINGS RAISE THE POSSIBILITY OF
DEDIFFERENTIATED LIPOSARCOMA, BUT NO WELL DIFFERENTIATED ADIPOCYTIC TUMOR IS
SEEN AND IMMUNOSTAINS DO NOT SUPPORT THIS POSSIBILITY. UNSTAINED SECTIONS
WILL BE SUBMITTED TO ASSESS FOR CHOP GENE AMPLIFICATION.

- 2) BLOOD VESSEL, AORTA, MARGIN; BIOPSY:
- ARTERY WITH CALCIFIED ATHEROMA, NO TUMOR SEEN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

*** Report Electronically Signed Out ***

** Continued on next page **

~~ICD~~ ICD O-3
Sarcoma, undifferentiated, pleomorphic
8805/3 8802/3
Code to highest 8805/3
path Sarcoma NOS 8800/3
Site: Retroperitoneum C48.0
J 3/12/14

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]
MRN: [REDACTED]
Account #: [REDACTED]

Accession #: [REDACTED]
Physician: [REDACTED]
Service: [REDACTED]
Date of Report: [REDACTED]

----- Page 2 of 3

Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

1) The specimen is received fresh and labeled "radical resection of retroperitoneal mass, left iliac and distal aorta, left nephrectomy and left adrenal gland". It consists of a large multi-lobulated circumscribed firm mass measuring 12 x 10.5 x 9.8 cm; a segment of muscle is attached to the mass (muscle measures 6 x 4.5 x 2.5 cm). The mass is connected to the left kidney and perirenal fat, (kidney and fat measure 24 x 12 x 6.5 cm); previously lacerated left adrenal gland measures 4 x 2.5 x 0.5 cm. The distal margins of the renal artery and vein are identified and the left renal artery measures 5 cm in length and 0.8 cm in diameter. The left renal vein measures 5.5 cm in length and 0.9 cm in diameter. A proximal segment of left ureter is dilated and encased/obstructed by the mass. The left ureter measures 5.5 cm in length and 0.9 cm in diameter. A short segment of artery (abdominal aorta) measures 2.1cm in length and 1.2 cm in diameter; the artery is adherent to the mass and cut surface of artery shows atheroma. The surgical margins are inked black and cut surface reveals a 30% lobulated white areas intermixed with 70% hard ossified areas; there is no necrosis identified. Grossly tumor not appear to invade into muscle or artery. Left kidney measures 12.5 x 5.8 x 3.5 cm; a 2.5 cm subcapsular cyst containing clear fluid is identified in the lower pole of the left kidney; the renal cortex, medulla and renal pelvis appear unremarkable. Two lymph nodes are identified in the renal hilum (0.9 and 1.5 cm). Representative sections are submitted, TPS is given and photograph is taken. Additional sections from the myxoid area of the tumor and peri-renal fat are submitted. Grossly ossified tissue is decalcified.

Summary of sections:

AM -- anterior margin of mass
PM-- posterior margin of mass
IM -- inferior margin of mass
SM-- superior margin of mass
MM-- medial margin of mass
LM-- lateral margin of mass
T-- soft fatty areas of the tumor
TA-- tumor with adjacent encasing artery
TU-- tumor with encasing/obstructing left ureter
TO-- tumor with osteoid areas
RVM-- left renal artery and vein margin
RC-- left renal cortex
RM-- left renal medulla
C--renal cyst
LN-- hilar lymph nodes
A--left adrenal gland
PF--peri-renal fat

** Continued on next page **

[page 3 of 4]
SURGICAL PATHOLOGIC REPORT

Patient: [REDACTED]
MRN: [REDACTED]
Account #: [REDACTED]

Accession #: [REDACTED]
Physician: [REDACTED]
Service: [REDACTED]
Date of Report: [REDACTED]

Page 3 of 3

TM- myxoid area of the tumor

2). The specimen is received in formalin, labeled as "aortic margin", and it consists of an unoriented fragment of arterial intima showing atherosclerotic change with focal calcification measuring 3.1 x 1.5 x 0.2 cm. Entire specimen is submitted. Part of the specimen is decalcified.

Summary of sections:
U -- undesignated

Summary of Sections:

Part 1: SP: Radical resection of retroperitoneal mass, left iliac and distal aorta left nephrectomy adrenal glands

Block	Sect.	Site	PCs
1	a		1
1	am		0
1	c		1
1	im		1
1	lm		1
1	ln		1
1	mm		1
2	pf		2
1	pm		1
1	rc		1
1	rm		1
1	rvm		1
1	sm		1
15	t		15
2	ta		2
4	tm		4
6	to		6
2	tu		2

Part 2: SP: Aortic margin

Block	Sect.	Site	PCs
2	u		2

** End of Report **

Criteria	hw 1/22/14	Yes	No
Dual/Synchronous Primary	Noted	☐	☒

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	High grade sarcoma with myxofibrosarcoma like foci & osseous differentiation.	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	pleomorphic sarcoma (MFH)	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	At the time of diagnosis, based on the morphology, a diagnosis of high grade sarcoma & myxofibrosarcoma-like foci & osseous differentiation was rendered. A possibility of dedifferentiated liposarcoma was entertained but stains did not support the findings. Upon review, tumor is a pleomorphic	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form. Sarcoma & only focal areas of myxoid change & areas of osseous differentiation. The findings are most consistent with Undifferentiated pleomorphic sarcoma
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chair is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 1a2b2929-8cfc-40af-8503-81ebbd6b8288 (TCGA-DX-AATS.89F7E741-DFC6-47C4-B0C1-5A3C2FACAD7A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).